Gene-level copy-number profile of tumor specimen C3N-02149-02 from CPTAC case C3N-02149, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.4 years (23,517 days).
Specimen C3N-02149-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48a3301d-9ee9-48db-84df-ee615bf29f02.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02149-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/16b80e87-c15f-424b-a9ee-e875eed195d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 419; copy number 1: 653; copy number 2: 28,554; copy number 3: 20,033; copy number 4: 7,066; copy number 5: 1,327; copy number 6: 393; copy number 7: 255; copy number 8: 19; copy number 9: 166; copy number 11: 21.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,181 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,065,657–18,388,514, 5 genes, copy number 8: LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1.
- chr1:39,838,110–40,463,718, 21 genes, copy number 11: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, ZFP69B.
- chr1:42,658,335–47,179,271, 180 genes, copy number 6–9 (within-gene range 1–9) (broad region; genes not listed).
- chr1:75,918,873–83,861,023, 82 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:87,453,240–96,823,738, 170 genes, copy number 5–6 (broad region; genes not listed).
- chr1:227,393,554–229,558,707, 100 genes, copy number 5 (broad region; genes not listed).
- chr3:151,637,174–151,761,339, 2 genes, copy number 6 (within-gene range 3–6): LINC02066, AADACL2.
- chr3:151,759,747–151,762,011, 1 gene, copy number 6 (within-gene range 3–6): AC068647.1.
- chr3:169,003,022–172,448,456, 69 genes, copy number 5 (broad region; genes not listed).
- chr3:174,438,573–175,810,548, 1 gene, copy number 5 (within-gene range 3–5): NAALADL2.
- chr3:175,059,361–178,007,779, 37 genes, copy number 5: EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr12:45,173,064–54,497,688, 405 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:29,576,479–30,191,898, 1 gene, copy number 6 (within-gene range 3–6): PRKD1.
- chr14:29,811,916–40,390,547, 181 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:45,706,250–45,715,952, 1 gene, copy number 6: LINC02303.
- chr18:7,566,782–15,330,282, 218 genes, copy number 5–7 (broad region; genes not listed).
- chr18:25,818,234–27,247,188, 28 genes, copy number 6: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908.

Autosomal genes at a single copy (total copy number 1): 557. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
